Somatic mutation profile of tumor specimen MMRF_1841_1_BM_CD138pos (aliquot MMRF_1841_1_BM_CD138pos_T1_KBS5U_L06449) from MMRF case MMRF_1841, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 61.3 years (22,390 days).
Specimen MMRF_1841_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e7d5fd65-90d0-4dae-be8e-5f5ba786e05c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1841_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1841_1_PB_Whole_C2_KBS5U_L06495; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ece58bec-f543-4041-9488-ac050eee8a7b

The open-access MAF lists 130 somatic variants for this specimen: 57 protein-altering or splice-affecting, 12 silent, 61 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 51, 3'UTR 36, Intron 15, Silent 12, 5'UTR 6, 3'Flank 2, Splice Site 2, Splice Region 2, Nonsense Mutation 1, RNA 1, 5'Flank 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.1010G>T p.R337L | Missense Mutation (SNP) | VAF 40/42 reads (95%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.946); catalogued as rs121912664, CM012663, CM104660, COSV52665150, COSV52691988, COSV52828545; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ABCB11 | c.262G>C p.D88H | Missense Mutation (SNP) | VAF 66/141 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV99792304; called by muse, mutect2, varscan2
- AKAP13 | c.1100G>A p.R367H | Missense Mutation (SNP) | VAF 22/146 reads (15%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as rs367656156; called by muse, mutect2, varscan2
- ATP13A4 | c.1618G>A p.D540N | Missense Mutation (SNP) | VAF 61/211 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0.118); catalogued as rs1398590725; called by muse, mutect2, varscan2
- BAD | c.420G>T p.Q140H | Missense Mutation (SNP) | VAF 82/180 reads (46%) | SIFT tolerated (0.09); PolyPhen benign (0.031); catalogued as rs368322510; called by muse, mutect2, varscan2
- BAG6 | c.1915C>T p.P639S (on ENST00000676571; = p.P592S on NM_080702.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 46/97 reads (47%) | SIFT tolerated (0.09); PolyPhen benign (0.197); catalogued as rs1385908136; called by muse, mutect2, varscan2
- C7orf61 | c.377G>A p.C126Y | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1342423790; called by muse, mutect2, varscan2
- CCR3 | c.737C>T p.A246V | Missense Mutation (SNP) | VAF 76/223 reads (34%) | SIFT tolerated (0.5); PolyPhen benign (0.001); catalogued as rs756281359, COSV100656543, COSV62462751; called by muse, mutect2, varscan2
- CEP120 | c.2200C>G p.Q734E | Missense Mutation (SNP) | VAF 14/102 reads (14%) | SIFT tolerated (0.24); PolyPhen benign (0.007); catalogued as COSV60266856; called by muse, mutect2, varscan2
- CEP55 | c.326G>A p.R109K | Missense Mutation (SNP) | VAF 72/183 reads (39%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1259783333; called by muse, mutect2, varscan2
- CHAT | c.1935A>C p.E645D | Missense Mutation (SNP) | VAF 19/105 reads (18%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.726); catalogued as rs775011277; called by muse, mutect2, varscan2
- CRISP1 | c.610G>A p.D204N | Missense Mutation (SNP) | VAF 19/47 reads (40%) | SIFT tolerated (0.57); PolyPhen benign (0.178); catalogued as COSV59993442; called by muse, mutect2, varscan2
- DCLK2 | c.632C>A p.A211D | Missense Mutation (SNP) | VAF 80/171 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs868679057; called by muse, mutect2, varscan2
- DRD4 | c.382G>A p.A128T | Missense Mutation (SNP) | VAF 14/205 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs762397930; called by muse, mutect2
- ELN | c.2084G>T p.G695V (on ENST00000320399 / NM_001278939.1; = p.G662V on NM_000501.4) | Missense Mutation (SNP) | VAF 36/77 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.258); catalogued as rs782551181, CD133481, COSV52706574; called by muse, mutect2, varscan2
- FBXW2 | c.168C>A p.F56L | Missense Mutation (SNP) | VAF 147/278 reads (53%) | SIFT deleterious (0); PolyPhen benign (0.01); catalogued as COSV61597449; called by muse, mutect2, varscan2
- FYCO1 | c.1609A>C p.K537Q | Missense Mutation (SNP) | VAF 61/212 reads (29%) | SIFT tolerated (0.66); PolyPhen benign (0.028); catalogued as rs776997220; called by muse, mutect2, varscan2
- H4C11 | c.175C>G p.L59V | Missense Mutation (SNP) | VAF 36/90 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.291); catalogued as COSV100747965, COSV61827422; called by muse, mutect2, varscan2
- IGLV3-1 | c.76C>T p.P26S | Missense Mutation (SNP) | VAF 63/73 reads (86%) | SIFT tolerated (0.07); PolyPhen benign (0.341); catalogued as rs61736463; called by muse, mutect2, varscan2
- IGLV3-1 | c.214C>G p.R72G | Missense Mutation (SNP) | VAF 52/57 reads (91%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.505); catalogued as rs61731683; called by muse, mutect2, varscan2
- KIAA1958 | c.1405G>A p.D469N | Missense Mutation (SNP) | VAF 29/107 reads (27%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.864); catalogued as rs747183451; called by muse, mutect2, varscan2
- KIF9 | c.625A>G p.M209V | Missense Mutation (SNP) | VAF 41/119 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.065); catalogued as rs367826868; called by muse, mutect2, varscan2
- PGM5 | c.1228C>T p.R410W | Missense Mutation (SNP) | VAF 19/156 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs879986279; called by muse, mutect2, varscan2
- RBL1 | c.68C>T p.A23V | Missense Mutation (SNP) | VAF 19/53 reads (36%) | SIFT tolerated (0.19); PolyPhen benign (0.05); catalogued as rs1340571749; called by muse, mutect2, varscan2
- RMI1 | c.109G>A p.E37K | Missense Mutation (SNP) | VAF 14/182 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57935572; called by muse, mutect2
- RORB | c.1189G>A p.E397K (on ENST00000396204 / NM_001365023.1; = p.E386K on NM_006914.4) | Missense Mutation (SNP) | VAF 51/110 reads (46%) | SIFT tolerated (0.28); PolyPhen benign (0.159); catalogued as rs775496473, COSV65335109; called by muse, mutect2, varscan2
- SETD5 | c.1427C>T p.S476F | Missense Mutation (SNP) | VAF 83/241 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.157); catalogued as rs753275152; called by muse, mutect2, varscan2
- SNAPC1 | c.845A>T p.H282L | Missense Mutation (SNP) | VAF 96/159 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1176037788; called by muse, mutect2, varscan2
- STAMBP | c.375+1G>A p.X125_splice | Splice Site (SNP) | VAF 25/47 reads (53%) | catalogued as rs765777459; called by muse, mutect2, varscan2
- THSD4 | c.580C>T p.L194F | Missense Mutation (SNP) | VAF 28/217 reads (13%) | SIFT tolerated (0.72); PolyPhen benign (0.015); catalogued as rs943068331; called by muse, mutect2, varscan2
- TM7SF3 | c.1286T>A p.I429K | Missense Mutation (SNP) | VAF 22/33 reads (67%) | SIFT tolerated (0.06); PolyPhen benign (0.388); catalogued as COSV58003576; called by muse, varscan2
- TTN | c.29382C>A p.Y9794* (on ENST00000591111; = p.Y8867* on NM_133378.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 11/89 reads (12%) | catalogued as rs886055289; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ALDH3B2 | c.284T>G p.L95R | Missense Mutation (SNP) | VAF 48/104 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- AMH | c.668C>A p.S223Y | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.203); called by muse, mutect2
- ARID1B | c.4367A>G p.N1456S | Missense Mutation (SNP) | VAF 41/127 reads (32%) | SIFT tolerated (0.08); PolyPhen benign (0.292); called by muse, mutect2, varscan2
- ATRX | c.7397G>T p.G2466V | Missense Mutation (SNP) | VAF 50/122 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CCNT2 | c.1802G>T p.S601I | Missense Mutation (SNP) | VAF 71/140 reads (51%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- CEP350 | c.1663A>C p.K555Q | Missense Mutation (SNP) | VAF 56/121 reads (46%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.677); called by muse, mutect2, varscan2
- DLGAP4 | c.2344C>A p.P782T (on ENST00000339266 / NM_001365621.1; = p.P779T on NM_014902.6) | Missense Mutation (SNP) | VAF 85/169 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- EIF2S3 | c.1250T>G p.V417G | Missense Mutation (SNP) | VAF 73/162 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- FAM47A | c.1334G>T p.C445F | Missense Mutation (SNP) | VAF 25/123 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.268); called by muse, mutect2, varscan2
- FAM71C | c.446A>G p.Y149C | Missense Mutation (SNP) | VAF 7/86 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- GADL1 | c.36C>T p.D12= | Splice Region (SNP) | VAF 19/243 reads (8%) | called by muse, mutect2
- GLRX | c.149C>T p.A50V | Missense Mutation (SNP) | VAF 51/132 reads (39%) | SIFT tolerated (0.14); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- HECA | c.1345G>A p.D449N | Missense Mutation (SNP) | VAF 11/100 reads (11%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.995); called by muse, mutect2
- INPP4B | c.966A>C p.T322= | Splice Region (SNP) | VAF 38/83 reads (46%) | called by muse, mutect2, varscan2
- LRP2 | c.2513+1G>T p.X838_splice | Splice Site (SNP) | VAF 73/191 reads (38%) | called by muse, mutect2, varscan2
- NAV2 | c.5924C>A p.S1975Y (on ENST00000396087 / NM_001244963.2; = p.S1916Y on NM_145117.5) | Missense Mutation (SNP) | VAF 43/128 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.105); called by muse, mutect2, varscan2
- OTUD7A | c.786del p.L263Wfs*16 | Frame Shift Del (DEL) | VAF 6/42 reads (14%) | called by mutect2, pindel, varscan2
- PLEKHG4B | c.3302G>A p.R1101K (on ENST00000283426; = p.R1457K on NM_052909.5) | Missense Mutation (SNP) | VAF 31/194 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.023); called by muse, varscan2
- POR | c.1055A>G p.N352S | Missense Mutation (SNP) | VAF 19/99 reads (19%) | SIFT tolerated (0.74); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- RBFOX1 | c.404C>T p.T135I (on ENST00000641259; = p.T19I on NM_001308117.1) | Missense Mutation (SNP) | VAF 32/272 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.387); called by muse, mutect2, varscan2
- RNF144B | c.803T>C p.I268T | Missense Mutation (SNP) | VAF 66/144 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.334); called by muse, mutect2, varscan2
- SYT8 | c.157G>T p.A53S | Missense Mutation (SNP) | VAF 33/73 reads (45%) | SIFT deleterious (0.04); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- TM7SF3 | c.1206T>G p.F402L | Missense Mutation (SNP) | VAF 28/43 reads (65%) | SIFT tolerated (0.08); PolyPhen benign (0.113); called by muse, varscan2
- ZNF462 | c.3224G>T p.G1075V | Missense Mutation (SNP) | VAF 39/142 reads (27%) | SIFT tolerated (0.08); PolyPhen benign (0.041); called by muse, varscan2
- ZNF8 | c.930C>A p.D310E | Missense Mutation (SNP) | VAF 59/176 reads (34%) | SIFT tolerated (1); PolyPhen benign (0.015); called by muse, mutect2
- ARRDC2 | c.285G>A p.E95= | Silent (SNP) | VAF 8/174 reads (5%) | called by muse, mutect2
- DDX31 | c.942G>A p.T314= | Silent (SNP) | VAF 7/48 reads (15%) | catalogued as rs1326090724; called by muse, mutect2
- EVPL | c.3129C>T p.R1043= | Silent (SNP) | VAF 110/235 reads (47%) | catalogued as rs759746268; called by muse, mutect2, varscan2
- FGR | c.1359C>G p.T453= | Silent (SNP) | VAF 17/141 reads (12%) | called by muse, mutect2, varscan2
- IGHV2-70D | c.303T>G p.L101= | Silent (SNP) | VAF 32/38 reads (84%) | called by muse, varscan2
- KCNQ4 | c.2034C>T p.S678= | Silent (SNP) | VAF 19/223 reads (9%) | catalogued as COSV61272194; called by muse, mutect2
- KIR3DL1 | c.648G>A p.V216= | Silent (SNP) | VAF 106/149 reads (71%) | called by muse, mutect2, varscan2
- PDZRN3 | c.1497G>A p.L499= | Silent (SNP) | VAF 36/120 reads (30%) | catalogued as rs1232708929; called by muse, mutect2, varscan2
- PTOV1 | c.324C>T p.Y108= | Silent (SNP) | VAF 20/237 reads (8%) | called by muse, mutect2
- REV3L | c.1164T>C p.N388= | Silent (SNP) | VAF 6/35 reads (17%) | catalogued as rs1454426045; called by muse, mutect2, varscan2
- TCEAL4 | c.24G>A p.P8= | Silent (SNP) | VAF 79/135 reads (59%) | catalogued as rs756583835; called by muse, mutect2, varscan2
- ZBTB37 | c.492C>T p.S164= | Silent (SNP) | VAF 53/119 reads (45%) | called by muse, mutect2, varscan2
- ASB9 | c.*397G>A | 3'UTR (SNP) | VAF 39/87 reads (45%) | called by muse, mutect2, varscan2
- BACE1 | c.942+64A>G | Intron (SNP) | VAF 3/44 reads (7%) | called by muse, mutect2
- CBFA2T2 | c.*752G>T | 3'UTR (SNP) | VAF 22/101 reads (22%) | called by muse, mutect2, varscan2
- CCDC141 | c.4325+976A>C | Intron (SNP) | VAF 34/68 reads (50%) | called by muse, mutect2, varscan2
- CHODL | c.*632T>G | 3'UTR (SNP) | VAF 35/133 reads (26%) | called by muse, mutect2, varscan2
- CLEC16A | c.*3067G>C | 3'UTR (SNP) | VAF 8/174 reads (5%) | called by muse, mutect2
- COL11A1 | c.-105T>A | 5'UTR (SNP) | VAF 35/59 reads (59%) | catalogued as rs976828697; called by muse, mutect2, varscan2
- COL6A4P1 | n.666C>T | RNA (SNP) | VAF 7/74 reads (9%) | catalogued as rs553133479; called by muse, mutect2
- DACH2 | c.1751-3841T>G | Intron (SNP) | VAF 43/128 reads (34%) | called by muse, mutect2, varscan2
- DPY19L2 | c.*690C>T | 3'UTR (SNP) | VAF 96/140 reads (69%) | called by muse, mutect2, varscan2
- EGLN3 | c.357+1816G>A | Intron (SNP) | VAF 10/167 reads (6%) | called by muse, mutect2
- EYA3 | c.*1750T>C | 3'UTR (SNP) | VAF 42/82 reads (51%) | called by muse, mutect2, varscan2
- EYA4 | c.*184del | 3'UTR (DEL) | VAF 9/49 reads (18%) | called by mutect2, pindel, varscan2
- FAM199X | c.*5610T>C | 3'UTR (SNP) | VAF 67/103 reads (65%) | catalogued as rs1449214336; called by muse, mutect2, varscan2
- FER | c.*503T>C | 3'UTR (SNP) | VAF 41/73 reads (56%) | called by muse, mutect2, varscan2
- FGF12 | c.-244C>A | 5'UTR (SNP) | VAF 110/341 reads (32%) | called by muse, mutect2, varscan2
- FUT8 | c.*1045C>G | 3'UTR (SNP) | VAF 5/28 reads (18%) | called by muse, mutect2, varscan2
- GAD2 | c.*34+259T>G | Intron (SNP) | VAF 31/77 reads (40%) | called by muse, mutect2, varscan2
- GOLIM4 | c.*857A>C | 3'UTR (SNP) | VAF 34/85 reads (40%) | called by muse, mutect2, varscan2
- H2BC12 | c.*38G>A | 3'UTR (SNP) | VAF 55/128 reads (43%) | called by muse, mutect2, varscan2
- HLA-A | c.-90T>A | 5'UTR (SNP) | VAF 70/145 reads (48%) | called by muse, mutect2, varscan2
- IGF2BP2 | c.*605G>A | 3'UTR (SNP) | VAF 58/168 reads (35%) | called by muse, mutect2, varscan2
- KIF1A | c.-27G>A | 5'UTR (SNP) | VAF 96/205 reads (47%) | catalogued as rs111963970; called by muse, mutect2, varscan2
- LRP1 | c.-112G>A | 5'UTR (SNP) | VAF 7/13 reads (54%) | called by muse, mutect2, varscan2
- LRRC75A | c.376-142G>A | Intron (SNP) | VAF 11/59 reads (19%) | called by muse, mutect2, varscan2
- LTB | c.162+100G>C | Intron (SNP) | VAF 31/69 reads (45%) | called by muse, mutect2, varscan2
- MFN1 | c.*1534T>A | 3'UTR (SNP) | VAF 34/109 reads (31%) | called by muse, mutect2, varscan2
- MIB1 | c.*940C>T | 3'UTR (SNP) | VAF 23/102 reads (23%) | called by muse, mutect2, varscan2
- MORC2 | c.68+39T>A | Intron (SNP) | VAF 63/74 reads (85%) | called by muse, mutect2, varscan2
- MORN4 | c.*1323C>T | 3'UTR (SNP) | VAF 11/103 reads (11%) | catalogued as rs534006696; called by muse, mutect2, varscan2
- MSI2 | c.63-34C>T | Intron (SNP) | VAF 12/42 reads (29%) | catalogued as COSV52367252; called by muse, mutect2, varscan2
- MXD1 | c.*4438G>A | 3'UTR (SNP) | VAF 7/113 reads (6%) | called by muse, mutect2
- NTRK2 | c.1397-54402G>T | Intron (SNP) | VAF 10/149 reads (7%) | called by muse, mutect2
- NYAP2 | c.*1792T>C | 3'UTR (SNP) | VAF 39/112 reads (35%) | catalogued as rs1211334143; called by muse, varscan2
- NYAP2 | c.*1864T>G | 3'UTR (SNP) | VAF 42/94 reads (45%) | called by muse, varscan2
- PDS5A | c.*896dup | 3'UTR (INS) | VAF 66/148 reads (45%) | catalogued as rs371161038; called by mutect2, varscan2
- PER2 | c.*97C>T | 3'UTR (SNP) | VAF 9/90 reads (10%) | catalogued as rs1559319444; called by muse, mutect2, varscan2
- PIR | c.566-65G>A | Intron (SNP) | VAF 14/57 reads (25%) | catalogued as rs774494117; called by muse, mutect2, varscan2
- PLK1 | c.*189T>C | 3'UTR (SNP) | VAF 59/150 reads (39%) | catalogued as rs1406516082; called by muse, mutect2
- PRKACB | c.-206C>T | 5'UTR (SNP) | VAF 4/54 reads (7%) | catalogued as rs1557887994, COSV65771414; called by muse, mutect2
- PTBP3 | chr9:112221604 C>T | 3'Flank (SNP) | VAF 31/56 reads (55%) | catalogued as rs1477141696; called by muse, mutect2, varscan2
- RAB11A | c.*2127T>C | 3'UTR (SNP) | VAF 26/57 reads (46%) | called by muse, varscan2
- RABL3 | c.*3T>A | 3'UTR (SNP) | VAF 16/358 reads (4%) | called by muse, mutect2
- RER1 | chr1:2405123 G>T | 3'Flank (SNP) | VAF 26/178 reads (15%) | called by muse, mutect2, varscan2
- RPUSD4 | c.*925A>C | 3'UTR (SNP) | VAF 54/128 reads (42%) | called by muse, mutect2, varscan2
- SCFD2 | c.1562-35175C>G | Intron (SNP) | VAF 8/73 reads (11%) | called by muse, mutect2, varscan2
- SEMA3E | c.*659A>T | 3'UTR (SNP) | VAF 59/133 reads (44%) | called by muse, mutect2, varscan2
- SLC47A2 | c.123+22del | Intron (DEL) | VAF 10/106 reads (9%) | called by mutect2, pindel
- SLC6A3 | c.*1935G>T | 3'UTR (SNP) | VAF 58/187 reads (31%) | called by muse, varscan2
- SLC6A3 | c.*1752G>T | 3'UTR (SNP) | VAF 38/132 reads (29%) | called by muse, varscan2
- SLC7A11 | c.*631C>A | 3'UTR (SNP) | VAF 62/122 reads (51%) | called by muse, mutect2, varscan2
- SYNJ2 | c.*1682T>A | 3'UTR (SNP) | VAF 9/40 reads (23%) | called by muse, mutect2, varscan2
- SYT15 | chr10:46578556 T>C | 5'Flank (SNP) | VAF 8/52 reads (15%) | called by muse, mutect2, varscan2
- TMEM260 | c.*1642G>C | 3'UTR (SNP) | VAF 8/38 reads (21%) | called by muse, mutect2, varscan2
- TNFAIP1 | c.*994G>A | 3'UTR (SNP) | VAF 33/122 reads (27%) | called by muse, mutect2, varscan2
- TXNRD1 | c.*1042_*1044del | 3'UTR (DEL) | VAF 17/87 reads (20%) | catalogued as rs367652526; called by mutect2, pindel, varscan2
- VAPA | c.418-5378G>T | Intron (SNP) | VAF 45/109 reads (41%) | called by muse, mutect2, varscan2
- VPS33B | c.701-105A>G | Intron (SNP) | VAF 107/181 reads (59%) | called by muse, mutect2, varscan2
- ZNF148 | c.*1523A>G | 3'UTR (SNP) | VAF 77/119 reads (65%) | called by muse, mutect2, varscan2
- ZNF44 | c.*514A>T | 3'UTR (SNP) | VAF 29/115 reads (25%) | called by muse, mutect2, varscan2
- ZNF704 | c.*3701T>C | 3'UTR (SNP) | VAF 32/69 reads (46%) | called by muse, mutect2, varscan2
